Somatic mutation profile of cancer-model specimen HCM-CSHL-0740-C18-85N (3D Organoid, passage 5; aliquot HCM-CSHL-0740-C18-85N-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0740-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.8 years (24,398 days).
Specimen HCM-CSHL-0740-C18-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f906a96-7926-4cfc-bac5-285319cd6071.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0740-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0740-C18-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9f85dd5-551d-4a93-86ce-2c95c2de45fb

The open-access MAF lists 298 somatic variants for this specimen: 228 protein-altering or splice-affecting, 59 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 195, Silent 59, Nonsense Mutation 13, Intron 8, Splice Site 5, Splice Region 4, Frame Shift Del 4, Frame Shift Ins 3, In Frame Del 2, RNA 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 228/553 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 281/286 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 103/277 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs149808995, COSV104400112; called by muse, mutect2, varscan2
- ADGRV1 | c.13850G>A p.G4617E | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182984071; called by muse, mutect2, varscan2
- AGRN | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 40/654 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs764063704; called by muse, mutect2
- AMER1 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 395/997 reads (40%) | catalogued as COSV57653855, COSV57662082; called by muse, mutect2, varscan2
- APC | c.4561G>T p.E1521* | Nonsense Mutation (SNP) | VAF 249/666 reads (37%) | catalogued as COSV57322883; called by muse, mutect2, varscan2
- ARHGAP12 | c.1520G>A p.S507N | Missense Mutation (SNP) | VAF 73/358 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs1391388188; called by muse, mutect2, varscan2
- ARHGAP15 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 248/250 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV54488028, COSV99711194; called by muse, mutect2, varscan2
- ASTN1 | c.3130G>T p.E1044* | Nonsense Mutation (SNP) | VAF 140/562 reads (25%) | catalogued as COSV62492108, COSV62507875; called by muse, mutect2, varscan2
- B4GALNT1 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 235/748 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV57542808; called by muse, mutect2, varscan2
- BMPR2 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 290/293 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs200339485; called by muse, mutect2, varscan2
- C17orf97 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 251/310 reads (81%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs782081322; called by muse, mutect2, varscan2
- CAMKV | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 568/573 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs573710169, COSV56556591, COSV99616148; called by muse, mutect2, varscan2
- CD5L | c.57G>A p.A19= | Splice Region (SNP) | VAF 138/343 reads (40%) | catalogued as rs143489369; called by muse, mutect2, varscan2
- CES1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 40/569 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746693909, COSV62089827; called by muse, mutect2
- CLSTN2 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 234/237 reads (99%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV71721529; called by muse, mutect2, varscan2
- CNP | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 489/494 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782788519; called by muse, mutect2, varscan2
- COL4A5 | c.4228C>T p.R1410C | Missense Mutation (SNP) | VAF 313/649 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs104886270, CM960393, COSV60377043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.3772G>A p.G1258R | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866225395; called by muse, mutect2
- CTR9 | c.3229C>T p.R1077* | Nonsense Mutation (SNP) | VAF 420/657 reads (64%) | catalogued as COSV63728658; called by muse, varscan2
- DCTD | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 67/458 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs766885547, COSV100830103; called by muse, mutect2, varscan2
- DENND3 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 132/588 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164686761, COSV52802220; called by muse, mutect2, varscan2
- DLEC1 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs765138386, COSV100341913; called by muse, mutect2
- DLG2 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs1226023254; called by muse, mutect2, varscan2
- DPEP1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 206/477 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV55360633; called by muse, mutect2, varscan2
- EIF4G1 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100072336; called by muse, mutect2
- ENAM | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs757420971; called by muse, mutect2
- EPB41L1 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 168/597 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs200279989; called by muse, mutect2, varscan2
- ETV3 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 330/737 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1042519523; called by muse, mutect2, varscan2
- EXOC3L1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 273/578 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1205484225, COSV99333968; called by muse, mutect2, varscan2
- FAM47A | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 46/834 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs1435553467, COSV100650088, COSV60499376; called by muse, mutect2
- FFAR2 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 440/440 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs145373857; called by muse, mutect2, varscan2
- FGFR2 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 304/595 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs998662110, COSV60643939; called by muse, mutect2, varscan2
- FPR2 | c.296A>T p.K99M | Missense Mutation (SNP) | VAF 181/359 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203326424; called by muse, mutect2, varscan2
- FREM2 | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 188/1278 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54826828, COSV54842467; called by muse, mutect2, varscan2
- GABRA5 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs576861235, COSV59475453; called by muse, mutect2, varscan2
- GPR119 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 298/1151 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV52275394; called by muse, mutect2, varscan2
- GRIN2A | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 173/406 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746978701, COSV58019618; called by muse, mutect2, varscan2
- GRTP1 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 1097/1100 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs776947918; called by muse, varscan2
- GSX1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 1383/1385 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57233287; called by muse, mutect2, varscan2
- HAUS1 | c.738G>A p.P246= | Splice Region (SNP) | VAF 20/196 reads (10%) | catalogued as rs760802716; called by muse, mutect2, varscan2
- HCAR1 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 131/700 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs147267914; called by muse, mutect2, varscan2
- HS1BP3 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 207/982 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs758703154; called by muse, mutect2, varscan2
- HUNK | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 484/487 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs772115970, COSV54226478; called by muse, mutect2, varscan2
- JMY | c.410A>T p.E137V | Missense Mutation (SNP) | VAF 226/977 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.081); catalogued as rs767360509; called by muse, mutect2, varscan2
- KCNT1 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 143/303 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV53702828; called by muse, mutect2, varscan2
- KCNT2 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV99656335; called by muse, mutect2, varscan2
- KRTAP4-11 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 603/1002 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs756399704, COSV101194914; called by muse, mutect2, varscan2
- LINGO1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 582/588 reads (99%) | SIFT tolerated (0.25); PolyPhen benign (0.111); catalogued as rs756041181; called by muse, mutect2, varscan2
- MAGEC1 | c.2901A>C p.E967D | Missense Mutation (SNP) | VAF 170/711 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV53568177; called by muse, mutect2, varscan2
- MAP3K15 | c.2252A>C p.K751T | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.646); catalogued as COSV58827337; called by muse, mutect2, varscan2
- MICALL2 | c.2640C>T p.G880= | Splice Region (SNP) | VAF 97/445 reads (22%) | catalogued as rs1385427871; called by muse, mutect2, varscan2
- MPDZ | c.2582C>G p.S861C | Missense Mutation (SNP) | VAF 52/638 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs1470491144; called by muse, mutect2
- MUC16 | c.13378T>G p.L4460V | Missense Mutation (SNP) | VAF 216/429 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.135); catalogued as COSV67495851; called by muse, mutect2, varscan2
- NAALAD2 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 121/377 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs950711606; called by muse, mutect2, varscan2
- NAV2 | c.3551G>A p.R1184Q (on ENST00000396087 / NM_001244963.2; = p.R1161Q on NM_145117.5) | Missense Mutation (SNP) | VAF 208/705 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs752367379, COSV60664981, COSV99051762; called by muse, mutect2, varscan2
- NKX2-6 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 327/764 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.47); catalogued as rs991694173; called by muse, mutect2, varscan2
- NLRP13 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 149/358 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1193094359, COSV100738237, COSV100738685; called by muse, mutect2, varscan2
- NOX5 | c.1511T>A p.I504N | Missense Mutation (SNP) | VAF 206/207 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1255084042; called by muse, mutect2, varscan2
- OR1I1 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 301/303 reads (99%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs147609807; called by muse, mutect2, varscan2
- OR7G3 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 150/321 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59640707; called by muse, mutect2, varscan2
- OR8K3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 144/528 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as rs755503510; called by muse, mutect2, varscan2
- PCDH11X | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 88/365 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015996; called by muse, mutect2, varscan2
- PCDHA3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 361/684 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65371842; called by muse, mutect2, varscan2
- PCDHB3 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 326/893 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs1554272666, COSV50629424; called by muse, mutect2, varscan2
- PCDHGA9 | c.1942G>C p.D648H | Missense Mutation (SNP) | VAF 191/648 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772084097; called by muse, mutect2, varscan2
- PCLO | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 173/514 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV100438594, COSV61629629; called by muse, mutect2, varscan2
- PIH1D1 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 346/350 reads (99%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as rs773060882; called by muse, mutect2, varscan2
- POU3F4 | c.27C>A p.Y9* | Nonsense Mutation (SNP) | VAF 309/537 reads (58%) | catalogued as COSV64540595; called by muse, mutect2, varscan2
- POU4F1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 112/811 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.689); catalogued as rs1159888057; called by muse, varscan2
- POU4F2 | c.232A>G p.S78G | Missense Mutation (SNP) | VAF 279/899 reads (31%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1414203136; called by muse, mutect2, varscan2
- PROCR | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 270/1024 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs757907256; called by muse, mutect2, varscan2
- PRPF19 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 86/438 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs372158363; called by muse, mutect2, varscan2
- PTPRN2 | c.1554_1556+1del p.X518_splice | Splice Site (DEL) | VAF 136/372 reads (37%) | catalogued as rs745584393; called by mutect2, pindel, varscan2
- PVRIG | c.357A>C p.E119D | Missense Mutation (SNP) | VAF 249/763 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as rs1369370812; called by muse, mutect2, varscan2
- RIC8B | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773118905, COSV62695853; called by muse, mutect2, varscan2
- RNPEP | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 330/716 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767769940; called by muse, mutect2, varscan2
- RYR3 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 273/277 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781225171, COSV101215514; called by muse, mutect2, varscan2
- SAMD9 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 133/475 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV66075340; called by muse, mutect2, varscan2
- SCN7A | c.1632C>A p.F544L | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV101313213; called by muse, mutect2, varscan2
- SEL1L | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 155/483 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.278); catalogued as rs376067391, COSV60921719; called by muse, mutect2, varscan2
- SERPINB3 | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs778873893; called by muse, mutect2, varscan2
- SETMAR | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 290/293 reads (99%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.115); catalogued as rs553781514; called by muse, mutect2, varscan2
- SIAH3 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 1214/1215 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1193045104; called by muse, mutect2, varscan2
- SLC6A19 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 270/461 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs771770693, COSV58670995; called by muse, mutect2, varscan2
- STS | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs1214783952; called by muse, mutect2, varscan2
- SYNE1 | c.10288G>A p.G3430R (on ENST00000367255 / NM_182961.4; = p.G3437R on NM_033071.3) | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs1047722501, COSV54952483; called by muse, mutect2, varscan2
- TAF5L | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 84/500 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as rs751192828; called by muse, mutect2, varscan2
- TBRG1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 273/427 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV52516541; called by muse, mutect2, varscan2
- TECTA | c.4276G>A p.G1426S | Missense Mutation (SNP) | VAF 155/566 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143250687; called by muse, mutect2, varscan2
- TENM1 | c.6772G>A p.A2258T | Missense Mutation (SNP) | VAF 152/1091 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as rs377058853, COSV64431401; called by muse, mutect2, varscan2
- TEX26 | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 86/856 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV66840096; called by muse, mutect2
- TKTL2 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 143/590 reads (24%) | catalogued as rs569128837; called by muse, mutect2, varscan2
- TMEM127 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 343/776 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as rs746831347, COSV51497970; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TMEM132C | c.2852A>C p.K951T | Missense Mutation (SNP) | VAF 327/691 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59421132; called by muse, mutect2, varscan2
- TRAK2 | c.2702T>G p.V901G | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV60274667; called by muse, mutect2
- TRIM58 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 734/742 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760428256; called by muse, mutect2, varscan2
- TRIM71 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 334/338 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV101070415, COSV67472660; called by muse, mutect2, varscan2
- TTN | c.27368G>A p.G9123D (on ENST00000591111; = p.G8196D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 375/693 reads (54%) | PolyPhen probably damaging (0.959); catalogued as COSV100614414; called by muse, mutect2, varscan2
- TXNDC11 | c.2749G>A p.E917K (on ENST00000356957 / NM_001303447.2; = p.E890K on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 299/562 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1178197263; called by muse, mutect2, varscan2
- UBE3B | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 93/411 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs200362048, COSV99783896; called by muse, mutect2, varscan2
- UBXN11 | c.736G>A p.D246N (on ENST00000374221 / NM_183008.2; = p.D213N on NM_145345.2) | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs1437631876; called by muse, mutect2, varscan2
- USP19 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 448/450 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs745611822; called by muse, mutect2, varscan2
- USP7 | c.3254C>T p.A1085V | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs1021857066; called by muse, mutect2
- XKR4 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 216/733 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV59318070; called by muse, mutect2, varscan2
- ZNF606 | c.1763G>A p.R588K | Missense Mutation (SNP) | VAF 35/493 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV58705205, COSV58705544; called by muse, mutect2
- ZNF648 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 572/574 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs910726353, COSV60572288; called by muse, mutect2, varscan2
- ZNF804A | c.3155A>G p.Y1052C | Missense Mutation (SNP) | VAF 88/545 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56452629; called by muse, mutect2, varscan2
- ABCA13 | c.12650G>A p.R4217H | Missense Mutation (SNP) | VAF 331/867 reads (38%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ADAM10 | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAM33 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 181/670 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.14071G>C p.D4691H | Missense Mutation (SNP) | VAF 113/405 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- AKR1B15 | c.595T>G p.L199V | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.3428A>C p.E1143A (on ENST00000280772 / NM_001320874.2; = p.E277A on NM_001149.3) | Missense Mutation (SNP) | VAF 29/434 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- ANKS1A | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 607/907 reads (67%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ANKS1B | c.1946A>C p.K649T | Missense Mutation (SNP) | VAF 147/315 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.2936dup p.M979Ifs*6 | Frame Shift Ins (INS) | VAF 283/607 reads (47%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.2590C>G p.L864V | Missense Mutation (SNP) | VAF 94/794 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- AVPR1A | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 444/722 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- BICRA | c.849G>C p.Q283H | Missense Mutation (SNP) | VAF 364/760 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BPTF | c.4818C>G p.S1606R | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C12orf40 | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 136/204 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- C19orf67 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 227/500 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CATIP | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CCDC144A | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 176/411 reads (43%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD163 | c.1835G>T p.W612L | Missense Mutation (SNP) | VAF 222/774 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFH | c.1835A>G p.Y612C | Missense Mutation (SNP) | VAF 225/461 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRMP1 | c.1461G>A p.K487= | Splice Region (SNP) | VAF 27/278 reads (10%) | called by muse, mutect2, varscan2
- CSMD1 | c.7117T>G p.F2373V (on ENST00000520002; = p.F2372V on NM_033225.6) | Missense Mutation (SNP) | VAF 186/293 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- CTSV | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEFB114 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DGKZ | c.707A>T p.Q236L | Missense Mutation (SNP) | VAF 322/902 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH1 | c.4692C>G p.Y1564* | Nonsense Mutation (SNP) | VAF 254/256 reads (99%) | called by muse, mutect2, varscan2
- DNALI1 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELP6 | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 275/277 reads (99%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA2 | c.2915T>G p.V972G | Missense Mutation (SNP) | VAF 162/324 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- EVC2 | c.3016A>C p.T1006P | Missense Mutation (SNP) | VAF 14/395 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- FAM111B | c.1089A>C p.Q363H | Missense Mutation (SNP) | VAF 154/524 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM47B | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 268/765 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- FANCB | c.2_15dup p.A6* | Nonsense Mutation (INS) | VAF 70/240 reads (29%) | called by mutect2, varscan2
- FBN2 | c.8444A>T p.K2815M | Missense Mutation (SNP) | VAF 53/702 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2
- FOXO4 | c.152A>T p.E51V | Missense Mutation (SNP) | VAF 42/1268 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- FREM3 | c.369A>T p.Q123H | Missense Mutation (SNP) | VAF 302/941 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- GK | c.1623dup p.I542Yfs*4 (on ENST00000427190 / NM_001205019.2; = p.I536Yfs*4 on NM_001128127.2) | Frame Shift Ins (INS) | VAF 160/396 reads (40%) | called by mutect2, pindel, varscan2
- GLT8D2 | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 135/438 reads (31%) | called by muse, mutect2, varscan2
- H2BC4 | c.212T>G p.F71C | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELB | c.2870C>G p.S957C | Missense Mutation (SNP) | VAF 24/655 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2
- HIF1A | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGSF9B | c.2507A>C p.K836T | Missense Mutation (SNP) | VAF 286/783 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IL10RA | c.1308A>C p.E436D | Missense Mutation (SNP) | VAF 263/859 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL21R | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 110/809 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- IRGQ | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 123/635 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- KCNC1 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 245/813 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM5C | c.3512A>C p.K1171T | Missense Mutation (SNP) | VAF 246/829 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KHDC1 | c.434T>G p.V145G (on ENST00000370384 / NM_001251874.2; = p.V72G on NM_030568.5) | Missense Mutation (SNP) | VAF 111/507 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIF19 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 53/560 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- KRT35 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- LAMA2 | c.5249T>A p.L1750H | Missense Mutation (SNP) | VAF 126/236 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMTK2 | c.3433A>C p.S1145R | Missense Mutation (SNP) | VAF 219/729 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRIT3 | c.1036C>A p.L346I | Missense Mutation (SNP) | VAF 184/404 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LRRC23 | c.743A>T p.Q248L | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MAD1L1 | c.1957T>G p.S653A | Missense Mutation (SNP) | VAF 190/685 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEA10 | c.410A>C p.K137T | Missense Mutation (SNP) | VAF 246/948 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MAP7D3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 600/1190 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MB21D2 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 155/386 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MCPH1 | c.1117A>T p.R373* | Nonsense Mutation (SNP) | VAF 70/601 reads (12%) | called by muse, mutect2, varscan2
- MDN1 | c.16663C>T p.R5555* | Nonsense Mutation (SNP) | VAF 144/292 reads (49%) | called by muse, mutect2, varscan2
- MFSD3 | c.761A>T p.N254I | Missense Mutation (SNP) | VAF 652/1221 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- MICAL1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 273/494 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MKLN1 | c.337_340del p.E113Hfs*4 | Frame Shift Del (DEL) | VAF 26/174 reads (15%) | called by mutect2, pindel, varscan2
- MSN | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 281/889 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTA2 | c.147G>T p.R49S | Missense Mutation (SNP) | VAF 58/516 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MTM1 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 38/662 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC16 | c.22638G>T p.E7546D | Missense Mutation (SNP) | VAF 376/382 reads (98%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NANOGP8 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 48/581 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- NHLH2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 504/516 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOP2 | c.1083C>A p.Y361* (on ENST00000322166 / NM_001258308.2; = p.Y357* on NM_006170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 308/648 reads (48%) | called by muse, mutect2, varscan2
- NWD1 | c.3523A>C p.S1175R | Missense Mutation (SNP) | VAF 199/439 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NWD2 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2
- PAPPA2 | c.2263A>G p.N755D | Missense Mutation (SNP) | VAF 141/707 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA6 | c.1781T>G p.V594G | Missense Mutation (SNP) | VAF 256/660 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PCGF6 | c.674-32_680del p.X225_splice | Splice Site (DEL) | VAF 69/189 reads (37%) | called by mutect2, pindel, varscan2
- PHTF1 | c.1779G>A p.W593* | Nonsense Mutation (SNP) | VAF 120/121 reads (99%) | called by muse, mutect2, varscan2
- PLD2 | c.2524T>G p.F842V | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- PLXNA3 | c.5154_5156+1delinsA p.X1718_splice | Splice Site (DEL) | VAF 96/663 reads (14%) | called by pindel, varscan2*
- PRDM2 | c.4249C>T p.L1417F | Missense Mutation (SNP) | VAF 116/326 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PTK2 | c.2079G>T p.M693I | Missense Mutation (SNP) | VAF 144/422 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RAB40AL | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 145/871 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- RAB44 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 142/754 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAP2C | c.269T>C p.F90S | Missense Mutation (SNP) | VAF 238/493 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAVER2 | c.1664C>A p.T555K (on ENST00000294428 / NM_001366165.1; = p.T542K on NM_018211.4) | Missense Mutation (SNP) | VAF 113/513 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RFPL4A | c.341A>C p.D114A | Missense Mutation (SNP) | VAF 117/480 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RHOBTB2 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 251/566 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- RHOXF2 | c.176dup p.L60Vfs*46 | Frame Shift Ins (INS) | VAF 260/550 reads (47%) | called by mutect2, varscan2
- RIMKLA | c.482-1G>C p.X161_splice | Splice Site (SNP) | VAF 11/221 reads (5%) | called by muse, mutect2
- RIPPLY3 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RNPEPL1 | c.1015_1017del p.S339del | In Frame Del (DEL) | VAF 171/666 reads (26%) | called by pindel, varscan2
- RO60 | c.26A>T p.Q9L | Missense Mutation (SNP) | VAF 218/223 reads (98%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, varscan2
- SCN5A | c.5645C>A p.A1882D (on ENST00000333535 / NM_198056.3; = p.A1881D on NM_000335.5) | Missense Mutation (SNP) | VAF 99/512 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.286); called by mutect2, varscan2
- SCN9A | c.2741T>C p.F914S (on ENST00000303354; = p.F903S on NM_002977.3) | Missense Mutation (SNP) | VAF 235/727 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA3A | c.948T>G p.F316L | Missense Mutation (SNP) | VAF 9/295 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- SLC13A3 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- SLC6A15 | c.39T>A p.D13E | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.005); called by muse, mutect2
- SLF1 | c.47A>C p.K16T | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- SLITRK4 | c.1263T>A p.F421L | Missense Mutation (SNP) | VAF 72/874 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLITRK5 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 72/1264 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2
- STK24 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 88/1324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STRADA | c.550G>T p.D184Y (on ENST00000336174 / NM_001363786.1; = p.D147Y on NM_153335.6) | Missense Mutation (SNP) | VAF 260/261 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SUPT20H | c.1417G>A p.G473R (on ENST00000350612 / NM_001014286.3; = p.G474R on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/599 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SZT2 | c.1083_1090+12del p.X361_splice | Splice Site (DEL) | VAF 73/200 reads (37%) | called by mutect2, pindel, varscan2
- TCOF1 | c.743_744del p.V248Dfs*25 | Frame Shift Del (DEL) | VAF 126/638 reads (20%) | called by pindel, varscan2
- TMPRSS7 | c.850C>G p.L284V (on ENST00000452346; = p.L158V on NM_001042575.2) | Missense Mutation (SNP) | VAF 164/355 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TNRC6B | c.3148_3171dup p.L1050_S1057dup (on ENST00000454349 / NM_001162501.2; = p.L997_S1004dup on NM_015088.3) | In Frame Ins (INS) | VAF 68/85 reads (80%) | called by mutect2, varscan2
- TPM1 | c.287del p.E96Gfs*32 | Frame Shift Del (DEL) | VAF 139/447 reads (31%) | called by mutect2, pindel, varscan2
- TPRN | c.2_16del p.MAALG1_?5 | Translation Start Site (DEL) | VAF 464/522 reads (89%) | called by mutect2, varscan2
- TPTE | c.1316A>C p.K439T (on ENST00000618007 / NM_199261.4; = p.K421T on NM_199259.4) | Missense Mutation (SNP) | VAF 32/471 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2
- TRAPPC11 | c.3386C>A p.S1129Y | Missense Mutation (SNP) | VAF 116/537 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TREH | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 87/1173 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- TRPC5 | c.1951T>G p.F651V | Missense Mutation (SNP) | VAF 206/791 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC7B | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 297/453 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- UPK3A | c.525G>C p.L175F | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WASF3 | c.330A>C p.Q110H | Missense Mutation (SNP) | VAF 160/969 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- WDSUB1 | c.316T>C p.S106P | Missense Mutation (SNP) | VAF 125/508 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- WWOX | c.1141del p.R381Afs*24 | Frame Shift Del (DEL) | VAF 77/522 reads (15%) | called by mutect2, pindel, varscan2
- ZFP42 | c.213T>G p.C71W | Missense Mutation (SNP) | VAF 100/635 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZMYM2 | c.704_718del p.S235_V239del | In Frame Del (DEL) | VAF 114/1133 reads (10%) | called by mutect2, pindel
- ZNF469 | c.9581G>A p.S3194N (on ENST00000437464; = p.S3222N on NM_001367624.2) | Missense Mutation (SNP) | VAF 368/844 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALG12 | c.1242C>T p.Y414= | Silent (SNP) | VAF 389/391 reads (99%) | catalogued as rs121907935, CM024735; called by muse, mutect2, varscan2
- AMN1 | c.516C>T p.V172= | Silent (SNP) | VAF 107/451 reads (24%) | catalogued as rs369471800; called by muse, mutect2, varscan2
- ARHGAP39 | c.1011C>A p.G337= | Silent (SNP) | VAF 434/1192 reads (36%) | called by mutect2, varscan2
- ARHGAP4 | c.2814C>T p.G938= | Silent (SNP) | VAF 52/1030 reads (5%) | called by muse, mutect2
- ARL11 | c.33G>A p.A11= | Silent (SNP) | VAF 116/832 reads (14%) | catalogued as rs766455088, COSV56290961; called by muse, varscan2
- ASXL3 | c.3603T>C p.H1201= | Silent (SNP) | VAF 38/404 reads (9%) | called by muse, mutect2
- B3GNT7 | c.696C>T p.H232= | Silent (SNP) | VAF 151/825 reads (18%) | catalogued as rs372054406; called by muse, mutect2, varscan2
- BRCC3 | c.831G>A p.S277= | Silent (SNP) | VAF 288/648 reads (44%) | catalogued as rs781889631; called by muse, mutect2, varscan2
- BTN3A3 | c.789C>T p.L263= | Silent (SNP) | VAF 117/392 reads (30%) | catalogued as rs371725478; called by muse, mutect2, varscan2
- CDK12 | c.3921G>A p.Q1307= (on ENST00000447079 / NM_016507.4; = p.Q1298= on NM_015083.3) | Silent (SNP) | VAF 496/504 reads (98%) | called by muse, mutect2, varscan2
- CFAP74 | c.852G>A p.A284= | Silent (SNP) | VAF 183/474 reads (39%) | catalogued as rs376431848; called by muse, mutect2, varscan2
- CLSTN3 | c.1554G>A p.S518= | Silent (SNP) | VAF 176/384 reads (46%) | catalogued as rs756157048, COSV56934311; called by muse, mutect2, varscan2
- CREB1 | c.610C>T p.L204= (on ENST00000432329 / NM_134442.5; = p.L190= on NM_004379.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/332 reads (12%) | called by muse, mutect2, varscan2
- DNHD1 | c.4962G>C p.L1654= | Silent (SNP) | VAF 165/612 reads (27%) | called by muse, mutect2, varscan2
- DUSP9 | c.54G>A p.P18= | Silent (SNP) | VAF 560/1317 reads (43%) | called by muse, mutect2, varscan2
- EPHA4 | c.330T>C p.S110= | Silent (SNP) | VAF 78/676 reads (12%) | called by muse, mutect2, varscan2
- FFAR1 | c.27C>T p.F9= | Silent (SNP) | VAF 420/422 reads (100%) | catalogued as rs1369977946; called by muse, mutect2, varscan2
- GABRB3 | c.15G>A p.A5= | Silent (SNP) | VAF 331/337 reads (98%) | called by muse, mutect2, varscan2
- GPR101 | c.1359C>G p.V453= | Silent (SNP) | VAF 44/1312 reads (3%) | catalogued as COSV99981235; called by muse, mutect2
- HDAC3 | c.492G>C p.V164= | Silent (SNP) | VAF 57/477 reads (12%) | called by muse, mutect2, varscan2
- KMT2A | c.3456G>A p.S1152= | Silent (SNP) | VAF 383/559 reads (69%) | catalogued as rs782465215; called by muse, mutect2, varscan2
- LHX1 | c.192A>T p.A64= | Silent (SNP) | VAF 119/261 reads (46%) | catalogued as rs1487859281; called by muse, mutect2, varscan2
- LONRF3 | c.1383C>T p.D461= (on ENST00000371628 / NM_001031855.3; = p.D420= on NM_024778.5) | Silent (SNP) | VAF 366/814 reads (45%) | catalogued as COSV59150346; called by muse, mutect2, varscan2
- LPL | c.838T>C p.L280= | Silent (SNP) | VAF 32/329 reads (10%) | called by muse, mutect2, varscan2
- LRRC1 | c.516G>A p.Q172= | Silent (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- MICAL2 | c.4218A>G p.Q1406= | Silent (SNP) | VAF 60/706 reads (8%) | catalogued as rs760691892; called by muse, mutect2
- MNDA | c.610A>C p.R204= | Silent (SNP) | VAF 121/547 reads (22%) | catalogued as COSV63741058; called by muse, mutect2, varscan2
- MUSK | c.300G>C p.T100= | Silent (SNP) | VAF 84/212 reads (40%) | catalogued as rs180928221; called by muse, mutect2, varscan2
- MXRA5 | c.7128C>A p.P2376= | Silent (SNP) | VAF 326/666 reads (49%) | called by muse, mutect2, varscan2
- NPSR1 | c.99T>A p.T33= | Silent (SNP) | VAF 38/555 reads (7%) | called by muse, mutect2
- NR4A3 | c.927C>T p.C309= | Silent (SNP) | VAF 489/495 reads (99%) | catalogued as COSV100432421, COSV58248356; called by muse, mutect2, varscan2
- NRG2 | c.204G>A p.Q68= | Silent (SNP) | VAF 327/1396 reads (23%) | called by muse, varscan2
- NRG3 | c.1851T>C p.S617= (on ENST00000404547 / NM_001370084.1; = p.S593= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 161/479 reads (34%) | catalogued as rs768186755, COSV64555595; called by muse, mutect2, varscan2
- OPRK1 | c.27C>T p.R9= | Silent (SNP) | VAF 440/921 reads (48%) | catalogued as rs777175554; called by muse, mutect2, varscan2
- OR5AR1 | c.438G>T p.L146= | Silent (SNP) | VAF 178/550 reads (32%) | catalogued as rs151139570; called by muse, mutect2, varscan2
- PCDHB3 | c.1488G>T p.P496= | Silent (SNP) | VAF 168/751 reads (22%) | called by muse, varscan2
- PPP4R3B | c.1464A>G p.E488= | Silent (SNP) | VAF 28/296 reads (9%) | called by muse, mutect2
- PRAMEF5 | c.1224A>G p.L408= | Silent (SNP) | VAF 175/376 reads (47%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2370C>G p.L790= | Silent (SNP) | VAF 337/343 reads (98%) | called by muse, mutect2, varscan2
- REELD1 | c.1164C>T p.S388= | Silent (SNP) | VAF 140/473 reads (30%) | called by muse, mutect2, varscan2
- REEP6 | c.357C>T p.F119= | Silent (SNP) | VAF 126/346 reads (36%) | called by muse, mutect2, varscan2
- SCN1A | c.1911G>A p.A637= | Silent (SNP) | VAF 707/1158 reads (61%) | catalogued as rs192102141; ClinVar: likely benign; called by muse, mutect2, varscan2
- SELENOM | c.177C>T p.F59= | Silent (SNP) | VAF 40/351 reads (11%) | catalogued as rs1442390432; called by muse, mutect2, varscan2
- SLC39A12 | c.345T>C p.S115= | Silent (SNP) | VAF 19/361 reads (5%) | catalogued as COSV66199848; called by muse, mutect2
- SP140 | c.264G>T p.L88= | Silent (SNP) | VAF 90/434 reads (21%) | called by muse, mutect2, varscan2
- SPTA1 | c.1530T>C p.S510= | Silent (SNP) | VAF 69/480 reads (14%) | called by muse, mutect2, varscan2
- TBX18 | c.1137G>C p.G379= | Silent (SNP) | VAF 65/424 reads (15%) | called by muse, mutect2, varscan2
- TCF25 | c.1758G>A p.L586= | Silent (SNP) | VAF 22/426 reads (5%) | catalogued as rs773487834; called by muse, mutect2
- TENM4 | c.144C>T p.Y48= | Silent (SNP) | VAF 224/842 reads (27%) | catalogued as rs928730342, COSV53613360; called by muse, mutect2, varscan2
- TRAPPC11 | c.3387T>A p.S1129= | Silent (SNP) | VAF 115/537 reads (21%) | called by muse, mutect2, varscan2
- TRPV5 | c.1644C>T p.D548= | Silent (SNP) | VAF 454/766 reads (59%) | catalogued as rs751587914; called by muse, varscan2
- TSEN54 | c.906C>T p.S302= | Silent (SNP) | VAF 584/590 reads (99%) | catalogued as rs774219646; called by muse, varscan2
- TSPAN10 | c.1101C>T p.P367= (on ENST00000574882 / NM_001290212.1; = p.P329= on NM_031945.4) | Silent (SNP) | VAF 763/768 reads (99%) | called by muse, mutect2, varscan2
- UNC79 | c.222T>C p.P74= | Silent (SNP) | VAF 16/558 reads (3%) | catalogued as COSV56392272; called by muse, mutect2
- UNC93A | c.1254G>C p.L418= | Silent (SNP) | VAF 109/403 reads (27%) | called by muse, mutect2, varscan2
- VWF | c.6615A>G p.P2205= | Silent (SNP) | VAF 117/458 reads (26%) | catalogued as rs1477319264; called by muse, mutect2, varscan2
- XRN1 | c.342G>A p.K114= | Silent (SNP) | VAF 200/202 reads (99%) | called by muse, mutect2, varscan2
- ZBTB33 | c.1245C>T p.I415= | Silent (SNP) | VAF 21/786 reads (3%) | called by muse, mutect2
- ZNF385D | c.868A>C p.R290= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as COSV55755947; called by muse, mutect2, varscan2
- ATP2B4 | c.3309+5703A>T | Intron (SNP) | VAF 84/850 reads (10%) | called by muse, mutect2
- ATXN8OS | n.499+902C>T | Intron (SNP) | VAF 42/666 reads (6%) | called by muse, mutect2
- CTBP2 | c.58+11431C>A | Intron (SNP) | VAF 186/827 reads (22%) | called by muse, mutect2, varscan2
- FGF13 | c.218-30321G>A | Intron (SNP) | VAF 52/630 reads (8%) | catalogued as rs753712009, COSV59543165; called by muse, mutect2
- G6PD | c.771-97G>A | Intron (SNP) | VAF 229/948 reads (24%) | catalogued as rs1557230115; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-17156dup | Intron (INS) | VAF 121/468 reads (26%) | called by mutect2, varscan2
- NPAP1L | n.576G>T | RNA (SNP) | VAF 57/335 reads (17%) | called by muse, mutect2, varscan2
- OSBPL6 | c.987+4568A>G | Intron (SNP) | VAF 129/558 reads (23%) | catalogued as rs749224530; called by muse, mutect2, varscan2
- PASK | c.3333+98G>C | Intron (SNP) | VAF 109/409 reads (27%) | catalogued as rs747707740; called by muse, mutect2, varscan2
- TMEM116 | c.-162C>T | 5'UTR (SNP) | VAF 22/288 reads (8%) | called by muse, mutect2
- XIST | n.9515C>G | RNA (SNP) | VAF 120/462 reads (26%) | called by muse, mutect2, varscan2
